Somatic mutation profile of tumor specimen MP2PRT-PATFZK-TMP1-A (aliquot MP2PRT-PATFZK-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATFZK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,117 days).
Specimen MP2PRT-PATFZK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a19d932-c79a-409e-b550-d0be8c152abe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFZK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFZK-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2c0982e-d546-444b-a55c-6476b216dbfc

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 248/516 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, mutect2, varscan2
- ATP6V1D | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs1463498660; called by muse, mutect2, varscan2
- LUZP2 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs373551420; called by muse, mutect2, varscan2
- OR51A4 | c.497G>C p.R166T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs201205025; called by muse, mutect2
- OR5F1 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.822); catalogued as COSV99558885; called by muse, mutect2, varscan2
- ROBO2 | c.3472C>T p.R1158W | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs747971442, CM1514900, COSV59930369; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC91 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- FMN1 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 106/269 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAP1A | c.8037G>A p.M2679I | Missense Mutation (SNP) | VAF 110/221 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC4 | c.14601C>G p.H4867Q (on ENST00000463781 / NM_018406.7; = p.H631Q on NM_004532.6) | Missense Mutation (SNP) | VAF 173/393 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- UBA2 | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ECSIT | c.210G>T p.V70= | Silent (SNP) | VAF 14/530 reads (3%) | called by muse, mutect2
- PHYHIPL | c.129C>A p.G43= | Silent (SNP) | VAF 86/210 reads (41%) | called by muse, mutect2, varscan2
- TTC9B | c.249G>A p.E83= | Silent (SNP) | VAF 312/679 reads (46%) | called by muse, mutect2, varscan2
